Somatic mutation profile of tumor specimen C3L-03262-01 (aliquot CPT0189280007) from CPTAC case C3L-03262, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 68.3 years (24,929 days).
Specimen C3L-03262-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fd33881-87ff-4aed-a587-512d96f3311a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03262-31 (Blood Derived Normal), aliquot CPT0190210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91c11849-727e-4ea4-8eda-2881b1f73611

The open-access MAF lists 162 somatic variants for this specimen: 106 protein-altering or splice-affecting, 43 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 43, Nonsense Mutation 7, Intron 6, Splice Region 4, Splice Site 3, 3'UTR 3, RNA 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 21/246 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ACSM2A | c.1186G>A p.D396N (on ENST00000219054; = p.D317N on NM_001308169.2) | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV54583345, COSV54587238; called by muse, mutect2
- ALOX5 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151270582, COSV65553149; called by muse, mutect2
- B3GALT1 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs749376311, COSV59909342; called by muse, mutect2, varscan2
- BAP1 | c.120G>A p.Q40= | Splice Region (SNP) | VAF 16/582 reads (3%) | catalogued as COSV56239185; called by muse, mutect2
- BCORL1 | c.5041C>A p.P1681T | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV99499101; called by muse, mutect2
- CANX | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 23/203 reads (11%) | catalogued as COSV56005936; called by muse, mutect2, varscan2
- CATSPERG | c.1370G>T p.R457L | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV53045456; called by muse, mutect2
- CD93 | c.744C>A p.F248L | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV55665152; called by muse, mutect2
- FAM160A2 | c.1855C>T p.R619W (on ENST00000449352 / NM_001098794.2; = p.R633W on NM_032127.4) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs780305032, COSV99792400; called by mutect2, varscan2*
- FAM47A | c.1553G>T p.R518L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.077); catalogued as rs1334539034, COSV60494973; called by muse, varscan2
- GABRG3 | c.370G>T p.G124W | Missense Mutation (SNP) | VAF 34/316 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61516961; called by muse, mutect2, varscan2
- GPR137 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs761827195, COSV57403181; called by muse, mutect2
- IPMK | c.965G>A p.R322K | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV64244696; called by muse, mutect2, varscan2
- ITGA6 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV51222907; called by muse, mutect2
- KALRN | c.5066G>A p.R1689H | Missense Mutation (SNP) | VAF 42/554 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1439137300, COSV62568615; called by muse, mutect2
- LAMA2 | c.3977G>T p.R1326L | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70337596; called by muse, mutect2
- LRRN2 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 45/320 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as COSV65784225; called by muse, varscan2
- MAGEA1 | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV63118948; called by muse, mutect2
- MXRA5 | c.2735C>A p.T912K | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs767283500; called by muse, mutect2
- MYO7A | c.4013G>T p.R1338L | Missense Mutation (SNP) | VAF 30/514 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs778477059; called by muse, mutect2
- NALCN | c.1020C>A p.S340R | Missense Mutation (SNP) | VAF 15/287 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV51949001; called by muse, mutect2
- NEB | c.11982G>T p.Q3994H | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.891); catalogued as COSV51423580; called by muse, mutect2, varscan2
- OR2M5 | c.835A>T p.T279S | Missense Mutation (SNP) | VAF 166/449 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as COSV100822717; called by muse, mutect2, varscan2
- PCDH15 | c.2031C>G p.D677E | Missense Mutation (SNP) | VAF 40/586 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs770957641; called by muse, mutect2
- PCDH18 | c.2851G>T p.G951W | Missense Mutation (SNP) | VAF 15/362 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1230357753, COSV61267051, COSV61270663; called by muse, mutect2
- PCDHA2 | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 34/453 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1554119669; called by muse, mutect2
- PCLO | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as rs1404004609; called by muse, mutect2
- PLD1 | c.389T>A p.L130Q | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779293445; called by muse, mutect2
- PRKN | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 13/284 reads (5%) | catalogued as COSV58249706, COSV58282473; called by muse, mutect2
- PTPN5 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs142331022; called by muse, mutect2
- RNF128 | c.367G>T p.G123C | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55252504; called by muse, mutect2
- SKAP1 | c.180G>T p.G60= | Splice Region (SNP) | VAF 9/87 reads (10%) | catalogued as COSV61146016; called by muse, mutect2, varscan2
- ST3GAL3 | c.-30-1G>T | Splice Site (SNP) | VAF 18/228 reads (8%) | catalogued as COSV53511025; called by muse, mutect2
- TENM3 | c.2418C>A p.C806* | Nonsense Mutation (SNP) | VAF 16/302 reads (5%) | catalogued as COSV69301837; called by muse, mutect2
- TEX13C | c.2724G>T p.Q908H | Missense Mutation (SNP) | VAF 21/295 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV66745172; called by muse, mutect2
- UXS1 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1039146529; called by muse, mutect2
- VPS13D | c.7318A>G p.I2440V | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1557705946; called by muse, mutect2
- ABCB1 | c.3270G>T p.L1090F | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.098); called by muse, mutect2
- AC118470.1 | c.114+6C>A | Splice Region (SNP) | VAF 8/192 reads (4%) | called by muse, mutect2
- AHCY | c.1240G>T p.A414S | Missense Mutation (SNP) | VAF 40/480 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.146); called by muse, mutect2
- B3GALT1 | c.795C>A p.D265E | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMX | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 11/339 reads (3%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- CASP2 | c.584A>T p.Q195L | Missense Mutation (SNP) | VAF 29/442 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2
- CCDC33 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- CEMIP | c.2059G>T p.A687S | Missense Mutation (SNP) | VAF 25/343 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CHST7 | c.424T>C p.Y142H | Missense Mutation (SNP) | VAF 46/520 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- EEF1A2 | c.1318A>C p.N440H | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.389); called by muse, mutect2
- EPHA3 | c.2287T>G p.S763A | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- ESYT3 | c.976G>T p.G326W | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM124A | c.256G>T p.A86S (on ENST00000322475 / NM_001242312.2; = p.A122S on NM_145019.4) | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.011); called by muse, mutect2
- FANCA | c.1636C>G p.Q546E | Missense Mutation (SNP) | VAF 40/626 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- GABRA6 | c.796A>G p.K266E | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRID1 | c.1459G>T p.A487S | Missense Mutation (SNP) | VAF 19/322 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2
- HBS1L | c.707A>G p.K236R | Missense Mutation (SNP) | VAF 26/457 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- HDX | c.1943A>T p.Q648L | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- HS3ST3B1 | c.536A>C p.K179T | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2
- IL4R | c.209A>T p.E70V | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2
- INA | c.565C>A p.R189S | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNE5 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2
- KIF21A | c.2141C>G p.A714G (on ENST00000361418 / NM_001378440.1; = p.A701G on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- L3MBTL4 | c.190G>T p.V64F | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2
- LEPROTL1 | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 28/419 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- LINS1 | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2
- LRRN2 | c.1762C>T p.L588F | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.082); called by muse, mutect2
- LVRN | c.2382G>T p.L794F | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.104); called by muse, mutect2
- MACROD2 | c.280A>T p.S94C | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2
- MAP7D3 | c.889A>G p.T297A | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2
- MED12L | c.1210C>G p.P404A | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MICALL2 | c.1757G>A p.G586E | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.672); called by muse, mutect2
- MROH1 | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 62/677 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.01); called by muse, mutect2
- MROH1 | c.378G>A p.M126I | Missense Mutation (SNP) | VAF 54/532 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- NAV3 | c.1588C>A p.P530T | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2
- NLRP7 | c.2730G>T p.L910F (on ENST00000340844 / NM_206828.3; = p.L882F on NM_139176.3) | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NTRK3 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 32/370 reads (9%) | called by muse, mutect2
- OR4K15 | c.25T>A p.C9S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.088); called by muse, mutect2
- OTOG | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); called by muse, mutect2
- PARD6A | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 11/306 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2
- PCDHGA8 | c.2227G>T p.V743F | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.379); called by muse, mutect2
- PCDHGB4 | c.1871T>G p.V624G | Missense Mutation (SNP) | VAF 37/440 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PDLIM5 | c.800A>G p.D267G | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PLEKHA5 | c.2841G>T p.R947S | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2
- PLP2 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 31/438 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PMPCB | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- PPP3R2 | c.397G>T p.V133F | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRDM8 | c.155A>T p.Y52F | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2
- PRKD2 | c.1129G>T p.G377W | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- RAB41 | c.635C>A p.S212Y (on ENST00000374473 / NM_001363807.1; = p.S211Y on NM_001032726.3) | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2
- RAD18 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 28/308 reads (9%) | called by muse, mutect2
- RFK | c.425A>G p.N142S | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- RHOD | c.220+2T>A p.X74_splice | Splice Site (SNP) | VAF 11/179 reads (6%) | called by muse, mutect2
- RPS6KA1 | c.1331A>G p.Y444C | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- RSU1 | c.162G>T p.M54I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA5A | c.2659G>T p.E887* | Nonsense Mutation (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.755-4C>A | Splice Region (SNP) | VAF 12/155 reads (8%) | called by muse, mutect2
- SKIV2L | c.545-1G>T p.X182_splice | Splice Site (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- SLC35G5 | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 33/585 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.411); called by muse, mutect2
- SLC39A4 | c.1557C>A p.F519L (on ENST00000301305 / NM_001374839.1; = p.F494L on NM_017767.3) | Missense Mutation (SNP) | VAF 34/1111 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); called by muse, mutect2
- SLC5A1 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SPATA46 | c.677A>C p.E226A | Missense Mutation (SNP) | VAF 26/645 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2
- SRCAP | c.82A>T p.N28Y | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TFCP2L1 | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZKSCAN8 | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 20/189 reads (11%) | called by muse, mutect2, varscan2
- ZNF600 | c.1861C>A p.Q621K | Missense Mutation (SNP) | VAF 22/321 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.088); called by muse, mutect2
- ZSCAN1 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 36/527 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZSWIM8 | c.4637C>T p.S1546F (on ENST00000605216 / NM_001242487.2; = p.S1551F on NM_015037.3) | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.371); called by muse, mutect2
- ANKRD30B | c.864G>A p.A288= | Silent (SNP) | VAF 37/437 reads (8%) | catalogued as rs371639612; called by muse, mutect2
- ATF6B | c.798A>G p.T266= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs770926614; called by muse, mutect2, varscan2
- DTX4 | c.1854G>A p.K618= | Silent (SNP) | VAF 26/181 reads (14%) | called by muse, mutect2, varscan2
- F8 | c.2610T>C p.P870= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as CD020562, CD034856; called by muse, mutect2, varscan2
- FCER1G | c.258G>A p.Q86= | Silent (SNP) | VAF 23/363 reads (6%) | called by muse, mutect2
- FGF23 | c.549C>T p.D183= | Silent (SNP) | VAF 17/163 reads (10%) | catalogued as rs369808475; called by muse, mutect2, varscan2
- FMN2 | c.2112G>T p.V704= | Silent (SNP) | VAF 34/402 reads (8%) | catalogued as COSV60436667, COSV60441127; called by muse, mutect2
- GOLGA8S | c.234G>C p.P78= | Silent (SNP) | VAF 18/656 reads (3%) | called by muse, mutect2
- GOLGA8T | c.1197C>A p.G399= | Silent (SNP) | VAF 36/490 reads (7%) | catalogued as rs527828932; called by muse, mutect2, varscan2
- GSG1L | c.858G>A p.E286= (on ENST00000447459 / NM_001109763.2; = p.E131= on NM_144675.2) | Silent (SNP) | VAF 9/178 reads (5%) | catalogued as rs1244853418; called by muse, mutect2
- HOXC13 | c.819G>A p.K273= | Silent (SNP) | VAF 49/478 reads (10%) | called by muse, mutect2, varscan2
- HTR1B | c.510C>A p.I170= | Silent (SNP) | VAF 25/322 reads (8%) | called by muse, mutect2
- IQSEC3 | c.2979G>A p.L993= (on ENST00000538872 / NM_001170738.2; = p.L690= on NM_015232.1) | Silent (SNP) | VAF 30/195 reads (15%) | called by muse, mutect2, varscan2
- KIF21A | c.2001C>T p.S667= (on ENST00000361418 / NM_001378440.1; = p.S654= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/182 reads (14%) | catalogued as rs1299938782; called by muse, mutect2, varscan2
- LINS1 | c.960G>T p.V320= | Silent (SNP) | VAF 16/190 reads (8%) | called by muse, mutect2
- LIPI | c.615T>A p.P205= | Silent (SNP) | VAF 28/380 reads (7%) | called by muse, mutect2
- LOXHD1 | c.1032G>T p.T344= | Silent (SNP) | VAF 24/326 reads (7%) | called by muse, mutect2
- MAGEA1 | c.495C>G p.T165= | Silent (SNP) | VAF 18/248 reads (7%) | catalogued as rs1024865497, COSV63118463; called by muse, mutect2
- MAGEB3 | c.412C>T p.L138= | Silent (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- MYH7 | c.3612C>A p.G1204= | Silent (SNP) | VAF 26/614 reads (4%) | called by muse, mutect2
- NEIL2 | c.300A>G p.G100= | Silent (SNP) | VAF 20/388 reads (5%) | catalogued as rs1563259060; called by muse, mutect2
- NLRP3 | c.58T>C p.L20= | Silent (SNP) | VAF 30/690 reads (4%) | catalogued as rs549742778, COSV60219505; called by muse, mutect2
- NRG1 | c.168G>T p.R56= | Silent (SNP) | VAF 11/157 reads (7%) | catalogued as COSV55153673; called by muse, mutect2
- OR2T34 | c.153C>T p.I51= | Silent (SNP) | VAF 18/696 reads (3%) | catalogued as COSV100170268; called by muse, mutect2
- OR7E24 | c.201C>A p.V67= | Silent (SNP) | VAF 32/488 reads (7%) | called by muse, mutect2
- PLXNA3 | c.5058G>T p.L1686= | Silent (SNP) | VAF 26/344 reads (8%) | called by muse, mutect2
- PPIL2 | c.867C>T p.G289= | Silent (SNP) | VAF 26/318 reads (8%) | catalogued as rs764935326; called by muse, mutect2
- PRR23C | c.366G>T p.L122= | Silent (SNP) | VAF 20/262 reads (8%) | catalogued as rs1396477007; called by muse, mutect2
- RELN | c.918C>T p.V306= | Silent (SNP) | VAF 27/354 reads (8%) | catalogued as rs767544612; called by muse, mutect2
- RNPEP | c.1614C>T p.F538= | Silent (SNP) | VAF 33/261 reads (13%) | called by muse, mutect2, varscan2
- SALL2 | c.1752C>T p.A584= | Silent (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- SCN8A | c.5794C>A p.R1932= | Silent (SNP) | VAF 62/726 reads (9%) | called by muse, mutect2
- SELENBP1 | c.768G>T p.L256= | Silent (SNP) | VAF 41/249 reads (16%) | called by muse, mutect2, varscan2
- SEMA6C | c.855C>T p.L285= | Silent (SNP) | VAF 32/628 reads (5%) | catalogued as COSV59001771; called by muse, mutect2
- SLC39A12 | c.288A>T p.L96= | Silent (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- SLC6A11 | c.1098C>A p.P366= | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as COSV99594559; called by muse, mutect2
- STAB1 | c.181C>A p.R61= | Silent (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- SULF2 | c.2142G>T p.L714= | Silent (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- TRIM15 | c.1281C>A p.T427= | Silent (SNP) | VAF 20/356 reads (6%) | called by muse, mutect2
- TRMT61B | c.783C>T p.S261= | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- VPS13A | c.18G>T p.V6= | Silent (SNP) | VAF 32/527 reads (6%) | called by muse, mutect2
- ZFHX4 | c.7665C>A p.S2555= | Silent (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- ZNF746 | c.1362C>T p.T454= | Silent (SNP) | VAF 22/372 reads (6%) | called by muse, mutect2
- AC244258.1 | n.531G>T | RNA (SNP) | VAF 9/124 reads (7%) | catalogued as rs1175547997; called by muse, mutect2
- AC245033.1 | c.1351-739G>A | Intron (SNP) | VAF 35/354 reads (10%) | catalogued as rs1377335945; called by muse, mutect2, varscan2
- C7orf25 | c.-55C>T | 5'UTR (SNP) | VAF 17/282 reads (6%) | catalogued as rs754433834; called by muse, mutect2
- CCNYL2 | n.624-2638G>T | Intron (SNP) | VAF 30/378 reads (8%) | called by muse, mutect2
- FER1L4 | n.2912T>A | RNA (SNP) | VAF 18/221 reads (8%) | called by muse, mutect2
- GATA3 | c.-66G>T | 5'UTR (SNP) | VAF 23/296 reads (8%) | called by muse, mutect2
- GCKR | c.*5A>G | 3'UTR (SNP) | VAF 28/330 reads (8%) | catalogued as rs1247595290; called by muse, mutect2
- METTL24 | c.787-7686_787-7673del | Intron (DEL) | VAF 5/53 reads (9%) | called by mutect2, pindel
- MLYCD | c.949-49G>A | Intron (SNP) | VAF 31/278 reads (11%) | catalogued as rs1458248874; called by muse, mutect2, varscan2
- MMP9 | c.1610+51G>T | Intron (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- NEU4 | c.-3-339G>T | Intron (SNP) | VAF 10/168 reads (6%) | catalogued as rs1401137567; called by muse, mutect2
- SNTB1 | c.*210G>A | 3'UTR (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- TMEM179 | c.*2126C>A | 3'UTR (SNP) | VAF 27/339 reads (8%) | called by muse, mutect2
